Somatic mutation profile of tumor specimen TCGA-P5-A5EY-01A (aliquot TCGA-P5-A5EY-01A-11D-A27K-08) from TCGA case TCGA-P5-A5EY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 21.1 years (7,716 days).
Specimen TCGA-P5-A5EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be699aee-72a0-4527-b6e4-7d3cf721226f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EY-10A (Blood Derived Normal), aliquot TCGA-P5-A5EY-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f466ec5-84d3-44b3-a460-678f7efeb2b9

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FPR3 | c.321C>A p.I107= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV59331659, COSV59332669; called by muse, mutect2
